Surgical pathology report (de-identified scan), TCGA case TCGA-BR-A4J8, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-A4J8-01A (Primary Tumor).

[page 1 of 2]
Gross Description: Fragment of the stomach with the fragment of the esophagus with tumor up to 7.5x5.2 cm in size with invasion of whole wall thickness. In fatty tissue there are dense hyperemic lymph nodes up to 1.5 cm in their largest dimension. Omentum, spleen and surgical margins are without macroscopic changes.

Microscopic Description: Adenocarcinoma of the stomach, G3, with invasion into the perigastric fatty tissue. In the blood vessels lumen there are tumor emboli. Seven examined lymph nodes from the greater curvature and five examined lymph nodes from the lesser curvature demonstrated metastases of the adenocarcinoma. Surgical margins are without evidence of tumor growth. Omentum is with focal haemorrhages. Spleen demonstrates anaemia of the red pulp. Separately collected lymph nodes demonstrated histiocytosis, anthracosis.

Diagnosis Details: Tumor Features: Ulcerating, Tumor Extent: Perigastric fat, Venous Invasion: Present, Margins: Absent, Treatment Effect:

Comments: According to the 7th edition of the AJCC stage is T3N3aM0 (IIIB).

Formatted Path Reports: STOMACH TISSUE CHECKLIST

Specimen type: Subtotal gastrectomy

Tumor site: Cardia

ICD-O-3

Tumor size: 5.2 x 0 x 7.5 cm

adenocarcinoma, NOS 8140/3

Tumor features: None specified

Site: stomach, cardia, NOS C16.0

Histologic type: Adenocarcinoma

W
10/2/12

Histologic grade: Poorly differentiated

Tumor extent: Subserosa

Lymph nodes: 12/12 positive for metastasis (Greater and lesser curvature 12/12)

Lymphatic invasion: Not specified

Venous invasion: Present

Perineural invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

[page 2 of 2]
Comments: None

LM

9/23/12

Source: NCI Genomic Data Commons file a6729a6d-4c8a-4d78-9415-ff94ad234a02 (TCGA-BR-A4J8.35854151-AD82-446F-B2FC-FE3AFAE0FA60.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).